TCGA case TCGA-S7-A7WN — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: University Hospital Motol. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0024ab57-4036-4b0f-b7a1-040f97787022

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Czech Republic (Czechia); Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Pheochromocytoma, malignant: ICD-O-3 morphology code: 8700/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 40.0 years (14,611 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,133 days (3.1 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 800 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,133 days (3.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-S7-A7WN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-S7-A7WN-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-S7-A7WN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-S7-A7WN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,133 days; disease-specific survival: no event (censored), 1,133 days; disease-free interval: no event (censored), 1,133 days; progression-free interval: no event (censored), 1,133 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-S7-A7WN-01A-12D-A35H-01): tumor purity 0.73, ploidy 1.98, whole-genome doublings 0.
